TCGA case TCGA-44-6146 — Lung Adenocarcinoma (TCGA-LUAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Bronchus and lung; Tissue source site: Christiana Healthcare. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/0c0b610e-fe4c-406d-a5ed-5cc3b11dabf5

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 64 years; Vital status: Alive.

Diagnoses (3)
1. Mucinous adenocarcinoma (the primary disease): ICD-O-3 morphology code: 8480/3; ICD-10 code: C34.30; Tissue or organ of origin: Lower lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 64.0 years (23,378 days); Year of diagnosis: 2010; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIB; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Treatment intent type: Adjuvant; Days to treatment start: 44 days; Days to treatment end: 44 days; Number of cycles: 1; Treatment dose: 165 mg; Prescribed dose: 165; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Pemetrexed Disodium; Treatment intent type: Adjuvant; Days to treatment start: 44 days; Days to treatment end: 107 days; Number of cycles: 4; Treatment dose: 4,400 mg; Prescribed dose: 1100; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 66 days; Days to treatment end: 107 days; Number of cycles: 3; Treatment dose: 1,600 mg; Route of administration: Intravenous.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Prior malignancy of the prostate gland (histology not recorded by GDC).
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
3. Recurrence of diagnosis 1 (Mucinous adenocarcinoma). Age at diagnosis: 65.7 years (24,009 days); Days to diagnosis: 631 days (1.7 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease; Surgery, NOS to Locoregional Site.

Follow-up (5 entries)
- Days to follow up: 302 days; Disease response: Tumor Free.
- Day 631 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 631 days (1.7 years); Evidence of recurrence type: Convincing Image Source.
- ECOG performance status: 0; Timepoint: Other.
- ECOG performance status: 1; Timepoint: Adjuvant Therapy.
- Follow-up contact recording only the day: day 728.

Other clinical attributes
- DLCO (% of predicted): 76; FEV1/FVC after bronchodilator (%): 95; FEV1/FVC before bronchodilator (%): 88; FEV1 after bronchodilator (% of reference): 94; FEV1 before bronchodilator (% of reference): 87.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 15; Tobacco smoking quit year: 1980.

Biospecimens (5 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-44-6146-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 420 mg; Longest dimension: 2; Intermediate dimension: 0.8; Shortest dimension: 0.8.
  Slide TCGA-44-6146-01A-03-TSC: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 5; Percent lymphocyte infiltration: 20; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 40.
  Slide TCGA-44-6146-01A-04-TSD: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 5; Percent lymphocyte infiltration: 20; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 40.
  Slide TCGA-44-6146-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 10; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 0.
  Slide TCGA-44-6146-01A-01-BS1: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 90; Percent normal cells: 5; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 0.
- Sample TCGA-44-6146-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide TCGA-44-6146-01B-03-TS3: Section location: Top; Percent tumor cells: 79; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 20; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 3; Percent neutrophil infiltration: 1.
  Slide TCGA-44-6146-01B-03-BS3: Section location: Top; Percent tumor cells: 79; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 20; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 3; Percent neutrophil infiltration: 1.
  Slide TCGA-44-6146-01B-04-BS4: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 12; Percent monocyte infiltration: 3; Percent neutrophil infiltration: 1.
- Sample TCGA-44-6146-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-44-6146-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TCGA-44-6146-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Initial weight: 400 mg; Longest dimension: 1.5; Intermediate dimension: 0.9; Shortest dimension: 0.9.
  Slide TCGA-44-6146-11A-03-TS3: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 20; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 40.
  Slide TCGA-44-6146-11A-02-TS2: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 5; Percent neutrophil infiltration: 0.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Mucinous Adenocarcinoma; History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Tobacco smoking history indicator: 3; Anatomic organ subdivision: L-Lower; Pulmonary function test indicator: Yes.
- Drug treatment 1: Regimen number: 1; Pharmaceutical therapy drug name: Alimta.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Follow-up form 1: Treatment outcome first course: Complete Remission/Response; Tumor status: Tumor free.
- Follow-up form 2: Lost to follow-up: No; New tumor event surgery: No; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes.
- Follow-up form 2, New neoplasm event types: New tumor event type: Locoregional Recurrence.
- Follow-up form 2, Progression determined by list: New tumor event diagnosis evidence: Convincing Imaging.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Prostate.

GDC annotations on this case (curator notes; quoted as recorded):
- Prior malignancy: Prior malignancy prostate cancer. No systemic chemotherapy or radiation.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 728 days; disease-specific survival: no event (censored), 728 days; disease-free interval: event (new tumor event after initially disease-free), 631 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 631 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-44-6146-01A-11D-A273-01): tumor purity 0.7, ploidy 1.87, whole-genome doublings 0.
